Somatic mutation profile of tumor specimen C3N-02729-01 (aliquot CPT0148280010) from CPTAC case C3N-02729, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 45.7 years (16,705 days).
Specimen C3N-02729-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11b08271-ec78-4192-81ae-2cee939fbe8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02729-71 (Blood Derived Normal), aliquot CPT0148310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d2ed687-e97a-461e-bcd1-ca6927898db8

The open-access MAF lists 48 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, 5'UTR 2, 3'UTR 2, In Frame Del 1, 3'Flank 1, Intron 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 190/612 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- EFCAB6 | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs780860882, COSV99413849; called by muse, mutect2, varscan2
- GPR153 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs769601920, COSV64938574; called by muse, mutect2
- H3-3B | c.52dup p.R18Pfs*80 | Frame Shift Ins (INS) | VAF 17/103 reads (17%) | catalogued as rs779064600; called by mutect2, pindel, varscan2
- HERC2 | c.10981G>A p.V3661I | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs368367299; called by muse, mutect2
- HHLA1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as rs951560216; called by muse, mutect2, varscan2
- HSPBP1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 62/128 reads (48%) | catalogued as rs769289721; called by muse, mutect2, varscan2
- ITPKB | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1424288317; called by muse, mutect2
- MROH5 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs776389636, COSV101436213; called by muse, mutect2, varscan2
- OTOF | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs751650771, COSV55498169; called by muse, mutect2
- PCDHA3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.043); catalogued as COSV100974176; called by muse, mutect2, varscan2
- ADAM19 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ADD1 | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ANK1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDCP2 | c.1148A>T p.E383V | Missense Mutation (SNP) | VAF 22/475 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- COPS9 | c.22A>C p.M8L (on ENST00000607357 / NM_001163424.2; = p.M29L on NM_138336.1) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DNAH11 | c.7087A>G p.T2363A | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- LRFN5 | c.1899G>T p.W633C | Missense Mutation (SNP) | VAF 134/392 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- LRRC53 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAST4 | c.7056A>T p.R2352S (on ENST00000403625 / NM_001164664.2; = p.R2163S on NM_015183.3) | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- MIER1 | c.273_278del p.E93_E94del (on ENST00000355356 / NM_001077701.3; = p.E110_E111del on NM_020948.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- MRPL1 | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PEG10 | c.461T>A p.M154K (on ENST00000482108 / NM_001040152.2; = p.M188K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/383 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PITPNM3 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PSMC6 | c.208A>T p.I70F (on ENST00000612399; = p.I56F on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TACC2 | c.1305A>T p.E435D | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TOMM40 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- UAP1L1 | c.1238A>C p.E413A | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ULK1 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.056); called by muse, mutect2
- ZFHX4 | c.4507G>A p.G1503R | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- AOC1 | c.483C>T p.P161= | Silent (SNP) | VAF 18/340 reads (5%) | catalogued as rs1445443935; called by muse, mutect2
- DCDC1 | c.3888T>A p.S1296= (on ENST00000597505 / NM_001367979.1; = p.S403= on NM_020869.3) | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- NSD2 | c.2112G>A p.R704= | Silent (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- OR2T2 | c.720T>A p.A240= | Silent (SNP) | VAF 156/885 reads (18%) | called by muse, mutect2, varscan2
- OR2T35 | c.717T>A p.A239= | Silent (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- SHISA8 | c.390G>A p.L130= (on ENST00000457093; = p.L163= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- SLC32A1 | c.657C>T p.I219= | Silent (SNP) | VAF 187/547 reads (34%) | called by muse, mutect2, varscan2
- TAPT1 | c.729C>T p.F243= | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- TIAM1 | c.555C>A p.L185= | Silent (SNP) | VAF 22/453 reads (5%) | catalogued as COSV54562923; called by muse, mutect2
- TTN | c.16329G>A p.T5443= (on ENST00000591111; = p.T4516= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as rs748617936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWF | c.6747C>A p.V2249= | Silent (SNP) | VAF 28/786 reads (4%) | called by muse, mutect2
- FAM47E | c.*12_*14del | 3'UTR (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- GFUS | c.146+119C>T | Intron (SNP) | VAF 30/85 reads (35%) | catalogued as rs537984415; called by muse, mutect2, varscan2
- GLYATL1 | n.50G>A | RNA (SNP) | VAF 74/213 reads (35%) | called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6050663 G>A | 3'Flank (SNP) | VAF 37/191 reads (19%) | called by muse, mutect2, varscan2
- PTBP3 | c.*22T>C | 3'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- SLC25A21 | c.-190G>A | 5'UTR (SNP) | VAF 63/221 reads (29%) | catalogued as rs1466874320; called by muse, mutect2, varscan2
- TLK1 | c.-26dup | 5'UTR (INS) | VAF 94/232 reads (41%) | catalogued as rs761218345; called by mutect2, varscan2
